Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8343, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8343-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

■ y/o male with right renal mass.

Specimens Submitted:

- 1: KIDNEY AND PORTION OF ADRENAL, RIGHT, NEPHRECTOMY
- 2: LYMPH NODES, PARACAVAL AND PERICAVAL, EXCISION

AMENDED DIAGNOSIS:

1. KIDNEY AND PORTION OF ADRENAL, RIGHT, NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 6.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Tumor involves medium caliber vessels in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3 Tumor extends into major veins or invades the adrenal gland or perinephric tissues, but not beyond Gerota's fascia

2. LYMPH NODES, PARACAVAL AND PERICAVAL, EXCISION:

Lymph Nodes:

Not involved

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Number of nodes examined:6

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED] That report is superseded by the present document. The amendment consists of the following change:

Specimens Submitted:

ORIGINAL REPORT:

1:KIDNEY AND PORTION OF ADRENAL, LEFT, NEPHRECTOMY

AMENDED REPORT:

1:KIDNEY AND PORTION OF ADRENAL, RIGHT, NEPHRECTOMY

The responsible clinician has been notified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh labeled "right kidney and portion of adrenal" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 240 g in total. The kidney measures 13 x 7 x 5.5 cm. The attached ureter measures 4.5 cm in length and 0.2 cm in diameter. The attached renal vein measures 1.4 cm in length and 0.4 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a well defined tumor mass measuring 6.5 x 4 x 4 cm, located in the calluses and extend to the hilum. The biliary tract is not involved by the tumor. The tumor has a homogenous yellow tan rubbery to soft cut surface. A portion of unremarkable adherent gland is identified measuring 1.3 x 1 x 0.5 cm. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.7 cm. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections. Photos are taken.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

A- adrenal

2). The specimen is received in formalin, labeled "Paracaval and pericaval lymph nodes" and consists of six pink tan firm lymph nodes ranging from 1 to 2.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph nodes

Summary of Sections:

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Part 1: KIDNEY AND PORTION OF ADRENAL, RIGHT, NEPHRECTOMY

Block	Sect. Site	PCs
1	a	1
2	k	2
2	rp	2
4	t	4
2	thf	2
2	tk	2
2	tsf	2
1	uvm	1

Part 2: LYMPH NODES, PARACAVAL AND PERICAVAL, EXCISION

Block	Sect. Site	PCs
3	BLN	4
2	LN	4

Amendments

Original Diagnosis:

1. KIDNEY AND PORTION OF ADRENAL, LEFT, NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Chromophobe type

Tumor Size:

Greatest diameter is 6.5 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Not identified

Tumor involves medium caliber vessels in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3 Tumor extends into major veins or invades the adrenal gland or perinephric tissues, but not beyond Gerota's fascia

2. LYMPH NODES, PARACAVAL AND PERICAVAL, EXCISION:

Lymph Nodes:

[page 4 of 4]
[REDACTED] **SURGICAL PATHOLOGY REPORT** [REDACTED]

Not involved
Number of nodes examined:6

Source: NCI Genomic Data Commons file bb8595bd-84ab-4cbb-953e-5cd6766270c9 (TCGA-KL-8343.3A3ECFF1-7EE1-475B-8482-AA576AFFE1AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).